Somatic mutation profile of tumor specimen TCGA-XX-A89A-01A (aliquot TCGA-XX-A89A-01A-11D-A36J-09) from TCGA case TCGA-XX-A89A, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 68.4 years (25,000 days).
Specimen TCGA-XX-A89A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b3ab4ef-c43c-4184-a396-27c0c5398d85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XX-A89A-10A (Blood Derived Normal), aliquot TCGA-XX-A89A-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd736a96-25b5-431a-8adc-9f648b4b3bb2

The open-access MAF lists 175 somatic variants for this specimen: 133 protein-altering or splice-affecting, 40 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 126, Silent 40, Nonsense Mutation 6, 5'Flank 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP7A | c.1435C>T p.Q479* | Nonsense Mutation (SNP) | VAF 23/66 reads (35%) | catalogued as rs1569549695, COSV100430633; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 21/80 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1051G>C p.D351H | Missense Mutation (SNP) | VAF 29/96 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519739, COSV61684417, COSV61684645, COSV61684738; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRL1 | c.405G>C p.Q135H | Missense Mutation (SNP) | VAF 48/305 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV100529414, COSV100529791; called by muse, mutect2, varscan2
- AKAP13 | c.8063C>G p.S2688C (on ENST00000394518 / NM_007200.5; = p.S2692C on NM_006738.6) | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV100773559; called by muse, mutect2, varscan2
- ANKS1B | c.3587G>A p.G1196E (on ENST00000547776 / NM_152788.4; = p.G362E on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.837); catalogued as COSV59122809; called by muse, mutect2, varscan2
- ASL | c.1188C>G p.F396L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV100508868; called by muse, mutect2, varscan2
- ASNS | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99446182; called by muse, mutect2
- BICDL1 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV66907423; called by muse, mutect2, varscan2
- BIRC6 | c.14309G>T p.C4770F | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101428156, COSV70207001; called by muse, mutect2, varscan2
- BRMS1 | c.349C>G p.Q117E | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.87); PolyPhen benign (0.023); catalogued as COSV100240216, COSV60820714; called by muse, mutect2
- CACNA2D4 | c.2659G>A p.D887N | Missense Mutation (SNP) | VAF 55/201 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs745480640, COSV99765484; called by muse, mutect2, varscan2
- CALCRL | c.1197G>C p.W399C | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101130920, COSV66477536; called by muse, mutect2
- CAMSAP1 | c.1785G>C p.L595F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100409776; called by muse, mutect2, varscan2
- CCDC93 | c.1521G>A p.Q507= | Splice Region (SNP) | VAF 18/94 reads (19%) | catalogued as COSV100098641; called by muse, mutect2, varscan2
- CDH1 | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV55743127; called by muse, mutect2
- CDKL3 | c.601C>G p.L201V | Missense Mutation (SNP) | VAF 37/205 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54745381, COSV99527789; called by muse, mutect2, varscan2
- CEP170 | c.1798G>C p.E600Q | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.611); catalogued as COSV100316901; called by muse, mutect2, varscan2
- CLDN16 | c.33C>G p.F11L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV53228245, COSV99290046; called by muse, mutect2, varscan2
- CNIH2 | c.396G>C p.Q132H | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.117); catalogued as COSV100268388; called by muse, mutect2
- COL14A1 | c.4733G>A p.G1578E | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52846308, COSV99918834, COSV99920412; called by muse, mutect2, varscan2
- COQ5 | c.334G>C p.D112H | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99942277, COSV99942347; called by muse, mutect2, varscan2
- CYLC1 | c.35G>A p.R12K | Missense Mutation (SNP) | VAF 76/352 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.023); catalogued as rs761315149, COSV100254482; called by muse, mutect2, varscan2
- CYP4F22 | c.1049A>G p.N350S | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV99512733; called by muse, mutect2, varscan2
- DPYSL5 | c.190G>C p.D64H | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56514236, COSV99982197; called by muse, mutect2, varscan2
- EFNA1 | c.429G>C p.L143F | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100310310; called by muse, varscan2
- EPX | c.664C>G p.L222V | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.541); catalogued as COSV56595533, COSV56596236; called by muse, mutect2, varscan2
- FGD5 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as rs749435304, COSV53247320; called by muse, mutect2, varscan2
- FGD5 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.164); catalogued as COSV53237178, COSV99547856; called by muse, mutect2, varscan2
- FLNC | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as rs771092335, COSV57955747; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABRE | c.191G>A p.R64K | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV64819192; called by muse, mutect2, varscan2
- GAD1 | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.942); catalogued as COSV100713802; called by muse, mutect2, varscan2
- GJA10 | c.836G>A p.R279K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV101005335, COSV65354807; called by muse, mutect2, varscan2
- GJA8 | c.799C>G p.Q267E | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.294); catalogued as COSV53791354; called by muse, mutect2, varscan2
- GNG2 | c.157C>G p.P53A | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as rs1441365658, COSV100087559; called by muse, mutect2, varscan2
- GPC6 | c.1115G>C p.R372T | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.456); catalogued as COSV100988496; called by muse, mutect2, varscan2
- HNF4A | c.128C>G p.S43* | Nonsense Mutation (SNP) | VAF 15/80 reads (19%) | catalogued as CM051933, COSV100291303; called by muse, mutect2, varscan2
- HRAS | c.269T>G p.F90C | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99529936; called by muse, mutect2, varscan2
- HSPG2 | c.411C>G p.I137M | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV101012927; called by muse, mutect2, varscan2
- IFT172 | c.1212A>T p.E404D | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV99562236; called by muse, mutect2, varscan2
- IGHG4 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 55/284 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751881796; called by muse, mutect2, varscan2
- INTS4 | c.52C>G p.Q18E | Missense Mutation (SNP) | VAF 20/450 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV101417166, COSV71092071; called by muse, mutect2
- INTS7 | c.1294G>C p.E432Q | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV100877474; called by muse, mutect2, varscan2
- KCNA2 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as COSV100315914; called by muse, mutect2, varscan2
- KCNK9 | c.492C>G p.F164L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.02); catalogued as COSV57277714, COSV57284486; called by muse, mutect2, varscan2
- KDM3B | c.4148C>A p.S1383Y | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.167); catalogued as COSV100069435; called by muse, mutect2, varscan2
- KIAA1217 | c.2242C>G p.L748V | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as rs1274976289, COSV100286484; called by muse, mutect2, varscan2
- KMT2E | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.261); catalogued as COSV57582671; called by muse, mutect2, varscan2
- KNL1 | c.5311G>C p.E1771Q (on ENST00000346991 / NM_170589.5; = p.E1745Q on NM_144508.5) | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV100705734, COSV100706617; called by muse, mutect2, varscan2
- KRTAP12-3 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.207); catalogued as rs782814531, COSV59950457; called by muse, mutect2, varscan2
- LAMA2 | c.5682G>C p.E1894D | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101370360; called by muse, mutect2, varscan2
- LHX6 | c.629C>G p.S210W (on ENST00000373755 / NM_001242334.2; = p.S239W on NM_014368.5) | Missense Mutation (SNP) | VAF 57/272 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100493340; called by muse, mutect2, varscan2
- MAGEA11 | c.437A>G p.Q146R | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.69); catalogued as rs782024340, COSV100290461; called by muse, mutect2, varscan2
- MAGEC3 | c.665T>G p.F222C | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100025239; called by muse, mutect2, varscan2
- MAPKBP1 | c.3970G>A p.E1324K (on ENST00000456763 / NM_001128608.2; = p.E1318K on NM_014994.3) | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.28); catalogued as rs765800997, COSV52957553; called by muse, mutect2, varscan2
- MATN2 | c.375G>C p.K125N | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.932); catalogued as COSV99646117; called by muse, mutect2, varscan2
- MDN1 | c.4576G>A p.D1526N | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101021178; called by muse, mutect2, varscan2
- MED13L | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.524); catalogued as COSV99928544; called by muse, mutect2, varscan2
- MOV10 | c.1347C>A p.F449L | Missense Mutation (SNP) | VAF 59/513 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as COSV100659507; called by muse, mutect2, varscan2
- MVB12A | c.93C>G p.I31M | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100396479; called by muse, mutect2, varscan2
- MYF6 | c.312G>C p.R104S | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57353486, COSV99952757; called by muse, mutect2, varscan2
- MYH8 | c.2511C>G p.F837L | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV101238997, COSV67959252; called by muse, mutect2, varscan2
- MYH9 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53383899; called by muse, mutect2, varscan2
- MYO3A | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99779326; called by muse, mutect2, varscan2
- NAIF1 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as rs144611939; called by muse, mutect2, varscan2
- NEDD4 | c.3895G>C p.E1299Q (on ENST00000508342 / NM_001284338.1; = p.E880Q on NM_006154.4) | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV100163626; called by muse, mutect2, varscan2
- NEK10 | c.2161C>G p.Q721E | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as COSV55355682, COSV99835077; called by muse, mutect2, varscan2
- NELFCD | c.1241C>T p.S414F (on ENST00000602795; = p.S396F on NM_198976.4) | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as COSV99413529; called by muse, mutect2, varscan2
- NLRP1 | c.727C>G p.Q243E | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99333803; called by muse, mutect2, varscan2
- NT5C1B | c.1381C>T p.Q461* (on ENST00000359846 / NM_001199086.2; = p.Q401* on NM_033253.4) | Nonsense Mutation (SNP) | VAF 11/105 reads (10%) | catalogued as COSV100409960; called by muse, mutect2, varscan2
- NTF4 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.108); catalogued as COSV100032236; called by muse, mutect2, varscan2
- NUDT16L1 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.817); catalogued as COSV52152990; called by muse, mutect2, varscan2
- OCIAD2 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56717356, COSV99906582; called by muse, mutect2, varscan2
- OGT | c.687C>G p.I229M | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV101035339; called by muse, mutect2, varscan2
- OTX2 | c.190G>C p.D64H (on ENST00000408990 / NM_172337.3; = p.D72H on NM_021728.4) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100257884; called by muse, mutect2, varscan2
- PCBP3 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV101234286; called by muse, mutect2, varscan2
- PCDH15 | c.4493T>C p.L1498P (on ENST00000617271 / NM_001142770.3; = p.A1486= on NM_001142769.3) | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100903801; called by muse, mutect2, varscan2
- PCDH9 | c.555G>C p.Q185H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV100119837; called by muse, mutect2, varscan2
- PCDHGA9 | c.1358C>G p.S453C | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV99536023; called by muse, mutect2, varscan2
- PIGO | c.2941G>C p.D981H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV99956606; called by muse, mutect2, varscan2
- PIK3IP1 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99314002; called by muse, mutect2, varscan2
- PLXNB2 | c.2296G>A p.D766N | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1442577954, COSV63779908; called by muse, mutect2, varscan2
- PMS1 | c.183C>G p.I61M | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100575595; called by muse, mutect2, varscan2
- PNKP | c.645C>G p.I215M | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99681672; called by muse, mutect2, varscan2
- PPFIA2 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs921218853, COSV61032719, COSV61056451; called by muse, mutect2
- PRB4 | c.98C>G p.S33* | Nonsense Mutation (SNP) | VAF 10/122 reads (8%) | catalogued as COSV54399944; called by muse, mutect2
- PRSS37 | c.250C>A p.Q84K | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100633837; called by muse, mutect2, varscan2
- PSMB8 | c.446C>T p.S149L (on ENST00000374882 / NM_148919.4; = p.S145L on NM_004159.5) | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs773754392, COSV62754466; called by muse, mutect2, varscan2
- PURG | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV99988852; called by muse, mutect2, varscan2
- RAB9B | c.432G>C p.E144D | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99686030; called by muse, mutect2, varscan2
- ROCK2 | c.186G>C p.L62F | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV99837261; called by muse, mutect2, varscan2
- RTL5 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs866272262, COSV101030011; called by muse, mutect2, varscan2
- SERPINB3 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.901); catalogued as COSV99379774; called by muse, mutect2, varscan2
- SHANK1 | c.6224C>G p.S2075C | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV53248333, COSV99520904; called by muse, mutect2, varscan2
- SHTN1 | c.975G>C p.Q325H | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV104394107, COSV99598793; called by muse, mutect2, varscan2
- SIM1 | c.2294G>A p.G765E | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99492254; called by muse, mutect2, varscan2
- SLC12A2 | c.1070C>T p.S357F | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99320952; called by muse, mutect2, varscan2
- SLC22A3 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV99278707; called by muse, mutect2, varscan2
- SLIT2 | c.4069G>A p.E1357K | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.075); catalogued as rs1276493567, COSV99882954; called by muse, mutect2, varscan2
- SMARCA5 | c.2562C>G p.I854M | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV99303716; called by muse, mutect2, varscan2
- SNTG1 | c.684G>C p.Q228H | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.28); catalogued as COSV99383065; called by muse, mutect2, varscan2
- SNX13 | c.1622G>A p.G541E | Missense Mutation (SNP) | VAF 74/332 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV101296825; called by muse, mutect2, varscan2
- ST8SIA1 | c.719C>A p.S240* | Nonsense Mutation (SNP) | VAF 18/79 reads (23%) | catalogued as COSV99683011; called by muse, mutect2, varscan2
- STAB2 | c.5932G>C p.D1978H | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV101185877; called by muse, mutect2, varscan2
- STAR | c.704C>G p.S235C | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); catalogued as rs773617644, COSV99378998; called by muse, mutect2, varscan2
- STRA6 | c.75C>G p.I25M | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV100120979; called by muse, mutect2, varscan2
- TAAR6 | c.918G>C p.M306I | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV99256622; called by muse, mutect2, varscan2
- TAMM41 | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as COSV99808776; called by muse, mutect2, varscan2
- TCN2 | c.973C>G p.Q325E | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV99308507; called by muse, mutect2, varscan2
- TLR2 | c.2192C>G p.A731G | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV99472250; called by muse, mutect2, varscan2
- TMEM209 | c.1060G>C p.E354Q | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV100390390; called by muse, mutect2, varscan2
- TNC | c.4966G>C p.D1656H | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs771928825, COSV100405560, COSV60779959; called by muse, varscan2
- TNC | c.4900G>T p.D1634Y | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.877); catalogued as COSV100405562; called by muse, varscan2
- TNIK | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs536847753, COSV99456639; called by muse, mutect2, varscan2
- TNPO3 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as COSV99602814; called by muse, mutect2, varscan2
- TOGARAM1 | c.3715C>T p.H1239Y | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV63890895, COSV63893385; called by muse, mutect2, varscan2
- TRA2B | c.734G>C p.G245A | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.794); catalogued as COSV99373239; called by muse, mutect2, varscan2
- TUBA8 | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100283108; called by muse, mutect2, varscan2
- TUBB4A | c.973G>C p.E325Q | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); catalogued as COSV99899952; called by muse, mutect2, varscan2
- UNC13C | c.6566C>G p.S2189C | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV99515378; called by muse, mutect2, varscan2
- VPS13C | c.10219G>A p.E3407K (on ENST00000644861 / NM_020821.3; = p.E3364K on NM_017684.5) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.98); PolyPhen benign (0.012); catalogued as COSV99828167; called by muse, mutect2, varscan2
- WIZ | c.5441C>A p.S1814Y (on ENST00000673675 / NM_001371589.1; = p.S719Y on NM_021241.3) | Missense Mutation (SNP) | VAF 34/271 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99653049; called by muse, mutect2, varscan2
- WTAP | c.932A>G p.N311S | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.025); catalogued as rs369657864; called by muse, mutect2, varscan2
- ZAN | c.5332G>A p.D1778N | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as rs1482302345, COSV61810028, COSV61813170; called by muse, mutect2, varscan2
- ZC3H12A | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100897693; called by muse, mutect2, varscan2
- ZDBF2 | c.4144C>G p.Q1382E | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV100984689, COSV65629087; called by muse, mutect2
- ZMAT1 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as COSV100858765; called by muse, mutect2, varscan2
- ZNF124 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV100517736; called by muse, mutect2, varscan2
- ZNF354B | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100482969; called by muse, mutect2, varscan2
- ZNF415 | c.1493G>A p.C498Y | Missense Mutation (SNP) | VAF 61/225 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs765728142, COSV99701399, COSV99701478; called by muse, mutect2, varscan2
- ZNF48 | c.1161C>A p.F387L | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.914); catalogued as COSV100198102; called by muse, mutect2, varscan2
- ZNF597 | c.73C>G p.Q25E | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs773056591, COSV57085991; called by muse, mutect2, varscan2
- ZNF695 | c.611G>C p.R204T | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.37); catalogued as COSV60585732; called by muse, mutect2, varscan2
- ABCA4 | c.4716G>A p.T1572= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as rs761897059, COSV64676724; called by muse, mutect2, varscan2
- ADCY4 | c.3180C>T p.Y1060= | Silent (SNP) | VAF 34/111 reads (31%) | catalogued as COSV100156478; called by muse, mutect2, varscan2
- ADGRF5 | c.2970A>T p.L990= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as COSV99345408; called by muse, mutect2, varscan2
- ANAPC11 | c.9G>A p.V3= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV100485825; called by muse, varscan2
- B4GAT1 | c.471C>T p.L157= | Silent (SNP) | VAF 14/132 reads (11%) | catalogued as COSV100240217; called by muse, mutect2, varscan2
- C10orf95 | c.636G>C p.L212= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV99493772; called by muse, mutect2
- C10orf99 | c.156G>C p.L52= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as COSV100929353; called by muse, mutect2, varscan2
- CACNA1F | c.189C>G p.A63= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV100544664; called by muse, mutect2, varscan2
- CGNL1 | c.3333G>A p.A1111= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs753380114, COSV99848039; called by muse, mutect2, varscan2
- DHFR | c.153G>A p.V51= | Silent (SNP) | VAF 35/124 reads (28%) | catalogued as COSV101459042; called by muse, mutect2, varscan2
- DMBT1 | c.7251C>T p.I2417= (on ENST00000338354 / NM_001377530.1; = p.I1660= on NM_004406.3) | Silent (SNP) | VAF 40/143 reads (28%) | catalogued as rs867396278, COSV57548461; called by muse, mutect2, varscan2
- DNAJC19 | c.350G>A p.*117= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV100700194; called by muse, mutect2, varscan2
- EFNA1 | c.423G>A p.L141= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100310307; called by muse, varscan2
- EFNA1 | c.489G>A p.E163= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100310311; called by muse, mutect2, varscan2
- EHBP1 | c.333G>A p.R111= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV50425275; called by muse, mutect2, varscan2
- GATA2 | c.1242C>T p.F414= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs751577185, COSV100351204; called by muse, mutect2
- GPAA1 | c.246G>A p.K82= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as COSV100284034, COSV60156237; called by muse, mutect2, varscan2
- GRIA4 | c.1959T>G p.S653= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV99230665; called by muse, mutect2, varscan2
- GRID1 | c.2916C>T p.N972= | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as rs138020946; called by muse, mutect2, varscan2
- HOXB1 | c.849C>T p.A283= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV99495439; called by muse, mutect2, varscan2
- IGHV3-72 | c.15G>C p.L5= | Silent (SNP) | VAF 23/164 reads (14%) | called by muse, mutect2
- KIFC1 | c.105C>T p.L35= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV100997098; called by muse, mutect2, varscan2
- LAMC2 | c.3297C>G p.L1099= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as COSV99917334, COSV99918087; called by muse, mutect2
- LDB2 | c.387C>T p.H129= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as rs764834270, COSV58769085; called by muse, mutect2, varscan2
- LRP1B | c.6549G>A p.L2183= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV101255496, COSV67220586; called by muse, mutect2, varscan2
- MLEC | c.588C>T p.V196= | Silent (SNP) | VAF 29/124 reads (23%) | catalogued as COSV99949629; called by muse, mutect2, varscan2
- NAA35 | c.252C>G p.L84= | Silent (SNP) | VAF 39/178 reads (22%) | catalogued as COSV100863319; called by muse, mutect2, varscan2
- NR0B1 | c.744C>G p.L248= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as rs1263620093, COSV100973507; called by muse, mutect2, varscan2
- NRAP | c.1074C>G p.L358= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as rs775904760, COSV100748391; called by muse, mutect2, varscan2
- OCRL | c.2674C>T p.L892= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as rs1233884460, COSV100843409; called by muse, mutect2, varscan2
- PPP1CB | c.138C>T p.L46= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV56089752, COSV99941776; called by muse, mutect2, varscan2
- PTCHD4 | c.723C>T p.L241= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs267601057, COSV100260592; called by muse, mutect2, varscan2
- PVALB | c.174C>T p.F58= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99342799; called by muse, mutect2, varscan2
- SLC12A1 | c.2256G>A p.A752= | Silent (SNP) | VAF 30/134 reads (22%) | catalogued as rs149454210; called by muse, mutect2, varscan2
- SURF4 | c.285C>T p.F95= | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as rs781818860, COSV100915195; called by muse, mutect2, varscan2
- TRPV1 | c.1602C>G p.L534= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as COSV99439360; called by muse, mutect2
- USPL1 | c.2154C>T p.V718= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs139903081, COSV99687201; called by muse, mutect2, varscan2
- ZC3H3 | c.1596C>G p.T532= | Silent (SNP) | VAF 40/169 reads (24%) | catalogued as COSV99367709; called by muse, mutect2, varscan2
- ZFHX4 | c.10458T>C p.H3486= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV99261519; called by muse, mutect2
- ZNF574 | c.1119C>T p.F373= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as rs113091672, COSV55903296; called by muse, mutect2, varscan2
- RS1 | c.-1G>C | 5'UTR (SNP) | VAF 59/226 reads (26%) | catalogued as COSV101183788; called by muse, mutect2, varscan2
- SUCO | chr1:172532615 C>G | 5'Flank (SNP) | VAF 20/100 reads (20%) | catalogued as COSV99742588; called by muse, mutect2, varscan2
